Gene-level copy-number profile of tumor specimen TCGA-13-0904-01A from TCGA case TCGA-13-0904, project TCGA-OV (Ovarian Serous Cystadenocarcinoma). Sex at birth: female; Vital status: Dead; Primary diagnosis: Serous cystadenocarcinoma, NOS; Tissue or organ of origin: Ovary; FIGO stage: Stage IIIC; Tumor grade: G3; Age at diagnosis: 63.7 years (23,278 days).
Specimen TCGA-13-0904-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary.
Source: NCI Genomic Data Commons open-access Gene Level Copy Number file TCGA-OV.637af986-3c73-4b1a-927a-d0c6ed7acf56.ascat3.gene_level_copy_number.v36.tsv, workflow ASCAT3 (allele-specific copy number) on an Affymetrix SNP 6.0 array pair, germline comparator TCGA-13-0904-10A (blood derived normal); Data Release 46.0 - August 10, 2026. Values are absolute (integer) total copy numbers per gene for 60,623 GENCODE v36 genes, of which 814 have no estimate. GDC also holds other gene-level copy-number files for this specimen, not rendered: ASCAT2; AscatNGS; ABSOLUTE LiftOver.
https://portal.gdc.cancer.gov/files/3a457580-5002-49f1-a237-993c2a5764fa

Most common (modal) total copy number across autosomal genes: 3 — above the diploid value of 2, consistent with a largely gained or genome-doubled tumor.
Genes by total copy number (all chromosomes): copy number 1: 4,356; copy number 2: 17,976; copy number 3: 18,698; copy number 4: 11,824; copy number 5: 4,547; copy number 6: 1,303; copy number 7: 115; copy number 8: 644; copy number 9: 346.
ABSOLUTE estimates for this specimen (TCGA Pan-Cancer Atlas, from the SNP 6.0 array, aliquot TCGA-13-0904-01A-02D-0399-01): tumor purity 0.89, ploidy 3.12, whole-genome doublings 1.

Homozygous deletions (total copy number 0; autosomes only): none.

Amplified relative to the modal value (total copy number ≥ 7, i.e. more than twice the modal value of 3; autosomes only): 1,105 genes in 5 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr7:134,744,252–159,233,377, 590 genes, copy number 8 (within-gene range 5–8) (broad region; genes not listed).
- chr11:118,401,602–135,075,908, 400 genes, copy number 8–9 (within-gene range 4–9) (broad region; genes not listed).
- chr14:47,444,106–51,730,727, 94 genes, copy number 7 (within-gene range 6–7) (broad region; genes not listed).
- chr15:51,829,628–51,947,295, 1 gene, copy number 7 (within-gene range 4–7): TMOD3.
- chr15:51,884,556–52,295,804, 20 genes, copy number 7 (within-gene range 4–7): Y_RNA, AC090971.2, RNU6-90P, AC090971.1, AC090971.3, LEO1, MAPK6, MAPK6-DT, AC090970.2, AC090970.1, AC023906.5, AC023906.2, AC023906.1, BCL2L10, GNB5, AC023906.3, AC023906.4, Y_RNA, CERNA1, MYO5C.

Autosomal genes at a single copy (total copy number 1): 4,073. Sex chromosomes are excluded from the deletion and amplification lists above because the expected copy number there depends on sex.
